Somatic mutation profile of cancer-model specimen HCM-CSHL-0600-C25-85A (3D Organoid, passage 7; aliquot HCM-CSHL-0600-C25-85A-01D-A82H-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0600-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 72.7 years (26,567 days).
Specimen HCM-CSHL-0600-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed5ec2f9-23f0-40cb-b895-9ed8bc70d409.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0600-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0600-C25-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/098dac72-efef-47e2-ae02-028a1dbf605f

The open-access MAF lists 73 somatic variants for this specimen: 54 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 17, Frame Shift Del 5, Frame Shift Ins 4, 5'UTR 2, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP164 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 243/512 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs387907310, CM127006, COSV54044695; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 162/384 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 221/221 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM4 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 164/425 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs755148242, COSV68067243; called by muse, mutect2, varscan2
- AHRR | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 145/294 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV57089133; called by muse, mutect2, varscan2
- ARHGEF4 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 100/377 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs777163056, COSV58119803, COSV58127430; called by muse, mutect2, varscan2
- B3GALT2 | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 139/252 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1344665355; called by muse, mutect2, varscan2
- BRF1 | c.761A>G p.K254R | Missense Mutation (SNP) | VAF 258/549 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.836); catalogued as COSV59270620; called by muse, mutect2, varscan2
- CAT | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 125/284 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144190885, CM055114; called by muse, mutect2, varscan2
- CDKN2A | c.225_243dup p.V82Rfs*44 | Frame Shift Ins (INS) | VAF 281/392 reads (72%) | catalogued as COSV58726442; called by mutect2, varscan2
- CRYBA4 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 13/249 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1459497417; called by muse, mutect2
- GRIP2 | c.1655C>T p.T552M (on ENST00000619221; = p.T455M on NM_001080423.4) | Missense Mutation (SNP) | VAF 161/796 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as rs1201005010; called by muse, mutect2, varscan2
- GYS2 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 155/325 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1336397751; called by muse, mutect2, varscan2
- HECW2 | c.44del p.R15Qfs*9 | Frame Shift Del (DEL) | VAF 127/406 reads (31%) | catalogued as COSV53655313, COSV53671757; called by mutect2, pindel, varscan2
- KCNH5 | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 198/397 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as rs1420114658; called by muse, mutect2, varscan2
- MAGI2 | c.2549G>A p.R850H | Missense Mutation (SNP) | VAF 171/378 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752723914, COSV62641661; called by muse, mutect2, varscan2
- NUP153 | c.3417G>C p.E1139D | Missense Mutation (SNP) | VAF 86/262 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV50447284; called by muse, mutect2, varscan2
- OR2A14 | c.274T>G p.S92A | Missense Mutation (SNP) | VAF 37/419 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as COSV68718767; called by muse, mutect2
- OR2J1 | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 127/440 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs753059801; called by muse, mutect2, varscan2
- PCDHA13 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 173/755 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs781929949, COSV56480768; called by muse, mutect2, varscan2
- PCDHGB4 | c.19del p.E7Sfs*40 | Frame Shift Del (DEL) | VAF 52/276 reads (19%) | catalogued as rs1314451260; called by mutect2, varscan2
- PDHA2 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 204/319 reads (64%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as rs1346482353, COSV54782257; called by muse, mutect2, varscan2
- PRR5L | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 177/354 reads (50%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as rs755502225, COSV61123573; called by muse, mutect2, varscan2
- RABL3 | c.600dup p.D201* | Frame Shift Ins (INS) | VAF 61/346 reads (18%) | catalogued as rs1339465735; called by mutect2, pindel, varscan2
- SELENOV | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 290/617 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1568454047; called by muse, mutect2, varscan2
- SLC12A9 | c.536G>A p.G179D | Missense Mutation (SNP) | VAF 384/807 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs1487179577; called by muse, mutect2, varscan2
- SORCS2 | c.1045G>A p.V349M | Missense Mutation (SNP) | VAF 126/363 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs377584831; called by muse, mutect2
- SYNJ1 | c.3043A>C p.N1015H | Missense Mutation (SNP) | VAF 12/372 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100448951; called by muse, mutect2
- ANKFN1 | c.915T>G p.Y305* | Nonsense Mutation (SNP) | VAF 24/368 reads (7%) | called by muse, mutect2
- ANKRD24 | c.877_887del p.M293Wfs*23 | Frame Shift Del (DEL) | VAF 214/533 reads (40%) | called by mutect2, pindel*
- CASP8 | c.285G>T p.R95S | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CLCN4 | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 268/270 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- CSNK1A1 | c.508A>G p.R170G | Missense Mutation (SNP) | VAF 157/360 reads (44%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CSPG4 | c.3842C>A p.P1281Q | Missense Mutation (SNP) | VAF 221/221 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EXOC1L | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 37/299 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- F5 | c.5804G>A p.R1935K | Missense Mutation (SNP) | VAF 100/280 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ITGA2 | c.1029T>A p.N343K | Missense Mutation (SNP) | VAF 57/324 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MASP2 | c.240C>A p.S80R | Missense Mutation (SNP) | VAF 15/406 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.053); called by muse, mutect2
- MASP2 | c.239G>T p.S80I | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.424); called by muse, mutect2
- MBD3 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 286/626 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- MDC1 | c.623_626del p.L208Rfs*8 | Frame Shift Del (DEL) | VAF 228/378 reads (60%) | called by mutect2, pindel, varscan2
- MTHFD1 | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 57/310 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2J1 | c.821T>A p.F274Y | Missense Mutation (SNP) | VAF 91/321 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PAF1 | c.937_939del p.F313del | In Frame Del (DEL) | VAF 114/290 reads (39%) | called by pindel, varscan2
- PKD2L2 | c.273G>C p.M91I | Missense Mutation (SNP) | VAF 128/277 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PRMT8 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 90/297 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SAMD9L | c.1219G>T p.D407Y | Missense Mutation (SNP) | VAF 155/336 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- TENM4 | c.7044G>A p.M2348I | Missense Mutation (SNP) | VAF 123/526 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TRAFD1 | c.1193_1196del p.N398Mfs*2 | Frame Shift Del (DEL) | VAF 138/298 reads (46%) | called by pindel, varscan2
- TRIM67 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 228/795 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF789 | c.304_305insTACACCAA p.K102Ifs*11 | Frame Shift Ins (INS) | VAF 36/142 reads (25%) | called by pindel, varscan2
- ZNF789 | c.305_306insCACCAAT p.K102Nfs*8 | Frame Shift Ins (INS) | VAF 55/183 reads (30%) | called by mutect2, varscan2*
- ZNF90 | c.446C>T p.T149I | Missense Mutation (SNP) | VAF 52/291 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ZUP1 | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 67/236 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- ABCA13 | c.10455A>T p.S3485= | Silent (SNP) | VAF 94/398 reads (24%) | called by muse, mutect2, varscan2
- B3GALNT1 | c.117C>G p.P39= | Silent (SNP) | VAF 143/324 reads (44%) | called by muse, mutect2, varscan2
- CDH18 | c.204A>T p.G68= | Silent (SNP) | VAF 63/295 reads (21%) | called by muse, mutect2, varscan2
- DPYSL4 | c.993C>T p.S331= | Silent (SNP) | VAF 239/354 reads (68%) | catalogued as rs755843621, COSV58306111; called by muse, mutect2, varscan2
- EVC2 | c.2073G>A p.A691= | Silent (SNP) | VAF 301/483 reads (62%) | catalogued as rs765197478; called by muse, mutect2, varscan2
- FGB | c.1458C>T p.P486= | Silent (SNP) | VAF 64/207 reads (31%) | catalogued as rs766560796; called by muse, mutect2, varscan2
- FLNC | c.5127C>T p.P1709= | Silent (SNP) | VAF 256/546 reads (47%) | catalogued as rs540345016, COSV57963191; ClinVar: likely benign; called by muse, mutect2, varscan2
- GLIPR1 | c.12A>G p.T4= | Silent (SNP) | VAF 124/260 reads (48%) | catalogued as rs1196953132; called by muse, mutect2, varscan2
- GPR83 | c.84C>T p.S28= | Silent (SNP) | VAF 53/922 reads (6%) | called by muse, mutect2
- HSD3B1 | c.225C>T p.D75= | Silent (SNP) | VAF 196/364 reads (54%) | catalogued as rs587677852, COSV52490180; called by muse, mutect2, varscan2
- LCT | c.309G>A p.Q103= | Silent (SNP) | VAF 117/380 reads (31%) | called by muse, mutect2, varscan2
- LOXL1 | c.81G>A p.Q27= | Silent (SNP) | VAF 494/495 reads (100%) | called by muse, mutect2, varscan2
- NALCN | c.3510C>T p.V1170= | Silent (SNP) | VAF 141/370 reads (38%) | catalogued as COSV51923309, COSV51967472; called by muse, mutect2, varscan2
- NUTM2A | c.981G>A p.R327= | Silent (SNP) | VAF 74/413 reads (18%) | called by muse, mutect2, varscan2
- NUTM2D | c.765G>A p.R255= | Silent (SNP) | VAF 206/578 reads (36%) | called by muse, varscan2
- OTOA | c.975C>A p.I325= | Silent (SNP) | VAF 323/671 reads (48%) | called by muse, mutect2, varscan2
- PCDH15 | c.168G>T p.L56= | Silent (SNP) | VAF 143/206 reads (69%) | catalogued as COSV57330805; called by muse, mutect2, varscan2
- DNASE1 | c.-363_-361del | 5'UTR (DEL) | VAF 246/497 reads (49%) | called by mutect2, pindel, varscan2
- LUC7L2 | c.-41C>T | 5'UTR (SNP) | VAF 327/692 reads (47%) | catalogued as rs1270104292; called by muse, mutect2, varscan2
